Somatic mutation profile of tumor specimen ALCH-B2ND-TTP1-A (aliquot ALCH-B2ND-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2ND, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.6 years (21,409 days).
Specimen ALCH-B2ND-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 620be594-c98d-4365-a4a2-c0485a4d0279.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2ND-NB1-A (Blood Derived Normal), aliquot ALCH-B2ND-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a5349c1-c871-4b76-a054-1148befef341

The open-access MAF lists 194 somatic variants for this specimen: 137 protein-altering or splice-affecting, 36 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 36, Nonsense Mutation 10, Intron 7, RNA 6, Splice Region 4, Splice Site 4, 5'Flank 3, 5'UTR 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.3037G>A p.G1013R | Missense Mutation (SNP) | VAF 42/520 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140593, CM950441, CM983865; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 53/145 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ADAMTSL5 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1216820169; called by muse, varscan2
- ADGRG4 | c.4507T>C p.S1503P | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54960195; called by muse, mutect2, varscan2
- AGMO | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV61125508; called by muse, mutect2, varscan2
- ALDH1L1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs370745999; called by muse, mutect2, varscan2
- AMOTL2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs746129024; called by muse, mutect2, varscan2
- ANKRD30A | c.236G>T p.W79L (on ENST00000611781; = p.W23L on NM_052997.2) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); catalogued as COSV64608809; called by muse, mutect2, varscan2
- ATM | c.3232C>G p.L1078V | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53742973; called by muse, mutect2
- ATP1A2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 138/512 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779985796, COSV63402581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C11orf96 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious, low confidence (0.01); catalogued as rs1221743830; called by muse, mutect2
- CACNA1E | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 91/421 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62384042, COSV62421776; called by muse, mutect2, varscan2
- CLVS2 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.802); catalogued as COSV51562993; called by muse, varscan2
- CORO2A | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 99/177 reads (56%) | catalogued as rs775356242, COSV100674026; called by muse, mutect2, varscan2
- CPNE4 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV70198062; called by muse, mutect2, varscan2
- CTNNA3 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs1234352433; called by muse, mutect2, varscan2
- CXCL2 | c.157C>G p.H53D | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV99933210; called by muse, mutect2
- DBX2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs778238452; called by muse, mutect2, varscan2
- DMXL1 | c.5302C>T p.H1768Y | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60723188; called by muse, mutect2, varscan2
- DNAH5 | c.9505C>T p.R3169C | Missense Mutation (SNP) | VAF 156/777 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768495886; called by muse, mutect2, varscan2
- DPP6 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 100/345 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs564612979; called by muse, varscan2
- ECT2 | c.2032A>G p.T678A (on ENST00000392692 / NM_001349098.2; = p.T647A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs1323784615; called by muse, mutect2, varscan2
- GRIN2A | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV58035436; called by muse, mutect2, varscan2
- GRM8 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100282003; called by muse, mutect2, varscan2
- HECW1 | c.4193A>T p.N1398I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs763378786; called by muse, mutect2, varscan2
- HMGCLL1 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51440930; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 47/178 reads (26%) | catalogued as rs757552862; called by muse, mutect2, varscan2
- IL9R | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54898149; called by muse, mutect2, varscan2
- KEAP1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50635496; called by muse, mutect2, varscan2
- LAMA2 | c.4228C>G p.P1410A | Missense Mutation (SNP) | VAF 108/611 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs747963781, COSV101370447; called by muse, mutect2, varscan2
- LRP1B | c.7556G>T p.G2519V | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV67250665; called by muse, mutect2, varscan2
- MRPS2 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1179377092; called by muse, mutect2, varscan2
- MYH2 | c.5405G>A p.R1802H | Missense Mutation (SNP) | VAF 189/494 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs777282924, COSV55447559, COSV55449799; called by muse, mutect2, varscan2
- MYNN | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs762547768, COSV62991031; called by muse, mutect2, varscan2
- MYOM1 | c.4060A>G p.R1354G | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55288881; called by muse, varscan2
- OR5D13 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.034); catalogued as COSV62334347; called by muse, mutect2, varscan2
- PCARE | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 30/838 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100527669; called by muse, mutect2
- PCDH10 | c.1658C>A p.A553E | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs757845067, COSV52092043; called by muse, mutect2, varscan2
- PGM1 | c.873G>T p.G291= | Splice Region (SNP) | VAF 60/157 reads (38%) | catalogued as COSV64301979; called by muse, mutect2, varscan2
- POP1 | c.1365G>A p.V455= | Splice Region (SNP) | VAF 18/411 reads (4%) | catalogued as rs1190409481; called by muse, mutect2
- RALYL | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV72819337; called by muse, mutect2, varscan2
- RGSL1 | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV54256694; called by muse, mutect2, varscan2
- RPEL1 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 71/576 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs556608138, COSV101483108; called by muse, mutect2, varscan2
- RYR2 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs376135032; called by muse, mutect2, varscan2
- SLC27A3 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as rs937469156; called by muse, mutect2, varscan2
- SLC5A8 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV73310577; called by muse, mutect2, varscan2
- SNPH | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as rs144751280; called by muse, mutect2, varscan2
- SUPT3H | c.343C>T p.R115* (on ENST00000371460 / NM_181356.3; = p.R104* on NM_003599.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as rs138104597; called by muse, mutect2, varscan2
- TCERG1L | c.1598C>G p.S533C | Missense Mutation (SNP) | VAF 81/381 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64054093; called by muse, mutect2, varscan2
- TP63 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 130/809 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1282887680, COSV53215379; called by muse, mutect2, varscan2
- VCAN | c.5092G>T p.A1698S | Missense Mutation (SNP) | VAF 92/343 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV54106176; called by muse, mutect2, varscan2
- VPS72 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 80/396 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs367571386; called by muse, mutect2, varscan2
- VWC2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100513960; called by muse, mutect2, varscan2
- XDH | c.3756G>T p.K1252N | Missense Mutation (SNP) | VAF 170/719 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV65149002; called by muse, varscan2
- ZNF568 | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1237713941; called by muse, mutect2, varscan2
- ZNF804B | c.1083C>A p.C361* | Nonsense Mutation (SNP) | VAF 88/300 reads (29%) | catalogued as COSV60833703; called by muse, mutect2, varscan2
- ZNF821 | c.274G>A p.E92K (on ENST00000425432 / NM_001376297.1; = p.E50K on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV57988189; called by muse, mutect2, varscan2
- ABCA9 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, varscan2
- ACAA2 | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ACTN2 | c.2138C>A p.T713K | Missense Mutation (SNP) | VAF 115/467 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM29 | c.2251C>A p.H751N | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS19 | c.40T>A p.C14S | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ALDH1L1 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ALKBH8 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- APOOL | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf71 | c.2318T>C p.V773A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C1orf74 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 169/422 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CCDC80 | c.2807A>T p.D936V | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDC20B | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 131/380 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CFHR3 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 200/503 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD7 | c.990A>C p.Q330H | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, mutect2
- CKAP5 | c.2230A>G p.K744E | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- COL28A1 | c.1302+2T>A p.X434_splice | Splice Site (SNP) | VAF 50/182 reads (27%) | called by muse, mutect2, varscan2
- COL5A2 | c.3940G>A p.D1314N | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A6 | c.3480C>A p.N1160K | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CPZ | c.1686C>G p.I562M (on ENST00000360986 / NM_001014447.3; = p.I551M on NM_003652.3) | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CXorf21 | c.862A>C p.T288P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DECR2 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- DIXDC1 | c.965C>A p.P322H (on ENST00000440460 / NM_001037954.4; = p.P111H on NM_033425.4) | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ELAVL2 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- EPHA7 | c.98-1G>T p.X33_splice | Splice Site (SNP) | VAF 41/133 reads (31%) | called by muse, varscan2
- ERICH3 | c.2812G>T p.A938S | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- EVX1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM90A20P | n.321A>G | Splice Region (SNP) | VAF 61/231 reads (26%) | called by muse, mutect2, varscan2
- FHL5 | c.335-1G>T p.X112_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | called by muse, varscan2
- FRY | c.8692T>A p.F2898I | Missense Mutation (SNP) | VAF 167/429 reads (39%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.53); called by muse, varscan2
- GABRA5 | c.960G>C p.M320I | Missense Mutation (SNP) | VAF 118/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GANAB | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GJB5 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- GLI3 | c.3242A>G p.D1081G | Missense Mutation (SNP) | VAF 133/443 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLRX3 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGB1 | c.7067A>T p.Y2356F | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GPR179 | c.4538G>A p.G1513E (on ENST00000621958; = p.G1512E on NM_001004334.4) | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- HEATR5B | c.4964C>T p.S1655L | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- HIBADH | c.533T>A p.V178D | Missense Mutation (SNP) | VAF 134/463 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD17B12 | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IGHA1 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 169/379 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRIG3 | c.1499A>T p.Q500L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRIT1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPLA1 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MAGEC1 | c.2708T>A p.L903* | Nonsense Mutation (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- METTL21C | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYO7B | c.4138G>T p.A1380S | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NCOA2 | c.233A>T p.K78M | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUCB1 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 96/345 reads (28%) | called by muse, mutect2, varscan2
- OCA2 | c.277T>C p.C93R | Missense Mutation (SNP) | VAF 124/393 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- OR5B12 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PAX1 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDH19 | c.2916G>T p.M972I (on ENST00000373034 / NM_001184880.2; = p.M924I on NM_020766.3) | Missense Mutation (SNP) | VAF 81/135 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PCDHGA11 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 120/216 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PKLR | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLSCR5 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLXDC1 | c.1187-1G>T p.X396_splice | Splice Site (SNP) | VAF 85/334 reads (25%) | called by muse, mutect2, varscan2
- POLR1H | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PROC | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- QSOX2 | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RLIM | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 114/225 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR3 | c.8671G>T p.A2891S (on ENST00000389232; = p.A2892S on NM_001036.6) | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SCARF1 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- SCYL2 | c.2570C>A p.S857* | Nonsense Mutation (SNP) | VAF 76/366 reads (21%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.1214G>A p.W405* | Nonsense Mutation (SNP) | VAF 70/187 reads (37%) | called by muse, mutect2, varscan2
- SLC17A6 | c.1301A>C p.H434P | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC7A11 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SPHKAP | c.3410T>C p.M1137T | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STYXL2 | c.1539C>A p.S513R | Missense Mutation (SNP) | VAF 121/230 reads (53%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1037C>A | Splice Region (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- THSD1 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- TLR8 | c.1927C>A p.R643S (on ENST00000218032 / NM_138636.5; = p.R661S on NM_016610.4) | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TRAV21 | c.127A>C p.S43R | Missense Mutation (SNP) | VAF 105/245 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TTN | c.52487C>T p.A17496V (on ENST00000591111; = p.A10072V on NM_003319.4) | Missense Mutation (SNP) | VAF 157/599 reads (26%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBGCP2 | c.2122A>G p.I708V | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS45 | c.696T>A p.Y232* | Nonsense Mutation (SNP) | VAF 54/242 reads (22%) | called by muse, mutect2, varscan2
- ZBTB20 | c.1439C>G p.T480R (on ENST00000474710 / NM_001164342.2; = p.T407R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 158/451 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZNF365 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 113/513 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF521 | c.3779T>A p.V1260D | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF610 | c.71T>C p.L24S | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNHIT6 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 23/334 reads (7%) | called by muse, mutect2
- ABL2 | c.2862G>A p.Q954= (on ENST00000502732 / NM_007314.4; = p.Q939= on NM_005158.5) | Silent (SNP) | VAF 354/813 reads (44%) | catalogued as rs1160731649; called by muse, mutect2, varscan2
- ACBD7 | c.150T>C p.D50= | Silent (SNP) | VAF 48/243 reads (20%) | called by muse, mutect2, varscan2
- ADGRA2 | c.3714G>A p.P1238= | Silent (SNP) | VAF 32/270 reads (12%) | called by muse, mutect2, varscan2
- ANK2 | c.10626T>C p.S3542= | Silent (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- ATP2C2 | c.2238C>T p.L746= | Silent (SNP) | VAF 31/275 reads (11%) | catalogued as rs768082918; called by muse, mutect2, varscan2
- C4orf50 | c.678C>A p.G226= (on ENST00000324058; = p.G1458= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- CDH22 | c.1041C>T p.D347= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
- CDH9 | c.1188A>G p.V396= | Silent (SNP) | VAF 46/189 reads (24%) | called by muse, mutect2, varscan2
- CHIC2 | c.201C>T p.S67= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- EIF4G1 | c.1605G>A p.K535= (on ENST00000346169 / NM_198241.3; = p.K339= on NM_004953.5) | Silent (SNP) | VAF 266/541 reads (49%) | called by muse, mutect2, varscan2
- FAAH2 | c.480G>T p.V160= | Silent (SNP) | VAF 68/115 reads (59%) | called by muse, mutect2, varscan2
- FASTKD2 | c.9A>G p.T3= | Silent (SNP) | VAF 19/324 reads (6%) | called by muse, mutect2
- GPATCH1 | c.84A>G p.P28= | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as rs1057488875; called by muse, mutect2, varscan2
- IL24 | c.51C>T p.F17= | Silent (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- IQCH | c.2494T>C p.L832= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs1418041267; called by muse, mutect2, varscan2
- LETMD1 | c.936G>C p.L312= | Silent (SNP) | VAF 149/476 reads (31%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2709G>A p.L903= | Silent (SNP) | VAF 56/93 reads (60%) | catalogued as rs1000480354, COSV53569081; called by muse, mutect2, varscan2
- MED13 | c.5073T>C p.P1691= | Silent (SNP) | VAF 103/416 reads (25%) | called by muse, mutect2, varscan2
- MMP16 | c.1176C>A p.I392= | Silent (SNP) | VAF 44/245 reads (18%) | catalogued as COSV54159099, COSV99691163; called by muse, mutect2, varscan2
- MYH2 | c.5325G>C p.L1775= | Silent (SNP) | VAF 192/484 reads (40%) | called by muse, mutect2, varscan2
- NNMT | c.549C>T p.L183= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as rs148805764; called by muse, mutect2, varscan2
- NPS | c.75A>G p.P25= | Silent (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- OR5D18 | c.867G>C p.L289= | Silent (SNP) | VAF 76/272 reads (28%) | catalogued as COSV61737852; called by muse, mutect2, varscan2
- OR9G1 | c.663C>A p.I221= | Silent (SNP) | VAF 62/390 reads (16%) | called by muse, mutect2
- PARP15 | c.1887T>A p.R629= (on ENST00000464300 / NM_001113523.3; = p.R395= on NM_152615.2) | Silent (SNP) | VAF 106/522 reads (20%) | called by muse, mutect2, varscan2
- PARVA | c.1038A>G p.P346= | Silent (SNP) | VAF 77/198 reads (39%) | called by muse, mutect2, varscan2
- PRTG | c.51G>T p.L17= | Silent (SNP) | VAF 50/323 reads (15%) | called by muse, mutect2, varscan2
- RAX | c.366C>A p.G122= | Silent (SNP) | VAF 78/208 reads (38%) | catalogued as rs369250755, COSV99900183; called by muse, mutect2, varscan2
- SLC26A4 | c.471C>A p.P157= | Silent (SNP) | VAF 130/401 reads (32%) | catalogued as COSV55915240; called by muse, mutect2, varscan2
- SPTA1 | c.3348G>T p.L1116= | Silent (SNP) | VAF 198/555 reads (36%) | catalogued as COSV63751111; called by muse, mutect2, varscan2
- TDRD15 | c.5418A>C p.S1806= | Silent (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- UNG | c.240G>T p.A80= (on ENST00000242576 / NM_080911.3; = p.A71= on NM_003362.4) | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- VCAN | c.5091T>C p.S1697= | Silent (SNP) | VAF 94/346 reads (27%) | called by muse, mutect2, varscan2
- ZDBF2 | c.1687C>A p.R563= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV65621821; called by muse, mutect2, varscan2
- ZNF423 | c.2412G>T p.L804= (on ENST00000563137 / NM_001379286.1; = p.L796= on NM_015069.4) | Silent (SNP) | VAF 58/131 reads (44%) | called by muse, mutect2, varscan2
- ZNF726 | c.558A>T p.S186= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084414 T>C | 5'Flank (SNP) | VAF 61/268 reads (23%) | called by muse, mutect2, varscan2
- ADAM3A | n.2064C>A | RNA (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.2377-122C>G | Intron (SNP) | VAF 50/200 reads (25%) | called by muse, mutect2, varscan2
- ADORA2A | c.-274-1819C>A | Intron (SNP) | VAF 116/472 reads (25%) | catalogued as rs1257991921; called by muse, mutect2, varscan2
- AL590867.2 | n.375G>T | RNA (SNP) | VAF 89/373 reads (24%) | called by muse, mutect2, varscan2
- ATP2C2 | c.2333+127del | Intron (DEL) | VAF 44/139 reads (32%) | called by mutect2, pindel, varscan2
- CD300LD | chr17:74592576 A>G | 5'Flank (SNP) | VAF 41/142 reads (29%) | catalogued as rs916057916; called by muse, mutect2, varscan2
- CHI3L1 | c.1012-81C>A | Intron (SNP) | VAF 105/459 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.3400C>A | RNA (SNP) | VAF 113/335 reads (34%) | called by muse, mutect2, varscan2
- FAM161A | c.*826A>T | 3'UTR (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2, varscan2
- GAB1 | c.73-19588C>T | Intron (SNP) | VAF 82/408 reads (20%) | called by muse, mutect2
- HERC2P3 | n.1694C>A | RNA (SNP) | VAF 36/226 reads (16%) | catalogued as rs534467273; called by mutect2, varscan2
- IKZF3 | c.-4C>G | 5'UTR (SNP) | VAF 47/206 reads (23%) | called by muse, mutect2, varscan2
- KLRD1 | c.*535G>T | 3'UTR (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- LINC02871 | n.974T>C | RNA (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- NFATC3 | c.-38C>G | 5'UTR (SNP) | VAF 54/245 reads (22%) | called by muse, mutect2
- NTM-AS1 | n.1856A>G | RNA (SNP) | VAF 28/147 reads (19%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.544-1809A>G | Intron (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- ZDHHC7 | c.315+1466A>T | Intron (SNP) | VAF 115/348 reads (33%) | called by muse, mutect2, varscan2
- ZEB2 | chr2:144520012 G>T | 5'Flank (SNP) | VAF 50/269 reads (19%) | called by muse, mutect2, varscan2
- ZIC4 | c.-6C>G | 5'UTR (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
